Gene-level copy-number profile of tumor specimen TCGA-IB-AAUQ-01A from TCGA case TCGA-IB-AAUQ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 50.1 years (18,315 days).
Specimen TCGA-IB-AAUQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.7b84d01a-dad6-42bf-8840-3573afbbaf8a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IB-AAUQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f025cd89-1df7-4c7c-94d6-154b51f2d83a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 11,558; copy number 2: 43,420; copy number 3: 3,937; copy number 4: 509; copy number 5: 137; copy number 6: 27; copy number 7: 20; copy number 9: 18; copy number 10: 8; copy number 14: 10; copy number 15: 27; copy number 17: 82.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IB-AAUQ-01A-22D-A40V-01): tumor purity 0.26, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 329 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,072,694–127,227,541, 1 gene, copy number 14 (within-gene range 2–14): CASC19.
- chr8:127,253,213–127,742,951, 9 genes, copy number 14: AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr10:81,870,778–84,003,479, 14 genes, copy number 5: AL096706.1, NRG3, AC010157.2, AC010157.1, NRG3-AS1, RNU6-441P, RNU6-478P, MARK2P15, LINC02650, AC069540.2, AC069540.1, RNU6-129P, AL390786.1, RNU1-65P.
- chr18:27,225,742–37,992,413, 143 genes, copy number 5–7 (broad region; genes not listed).
- chr19:27,638,483–30,085,893, 62 genes, copy number 6–15 (broad region; genes not listed).
- chr19:38,867,830–40,629,818, 100 genes, copy number 9–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,398. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
